Somatic mutation profile of tumor specimen 0DHV6B from CCDI case PBBUTU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.2 years (1,184 days).
Specimen 0DHV6B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fc0f188-5a04-430b-83e7-2ed1429f18b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHV65 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/600946e7-35c7-4d95-a52d-a6c2ebf4ddfe

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 2, Silent 1, 5'UTR 1, RNA 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDT1 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 48/571 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as rs553021912; called by muse, mutect2
- IGHMBP2 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 120/581 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.23); catalogued as rs761355302, COSV54823547; called by muse, mutect2, varscan2
- NLGN2 | c.1235A>G p.N412S | Missense Mutation (SNP) | VAF 58/455 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs1450604624; called by muse, mutect2, varscan2
- RNF40 | c.2962G>A p.A988T | Missense Mutation (SNP) | VAF 181/367 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as rs1170780879, COSV52700074; called by muse, mutect2, varscan2
- SEPTIN8 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 256/575 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1478199485; called by muse, mutect2, varscan2
- SIRPB1 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 201/479 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs781727801; called by muse, mutect2, varscan2
- TM9SF4 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 34/735 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs949415556; called by muse, mutect2
- TMPO | c.2042_2044del p.G681del | In Frame Del (DEL) | VAF 71/526 reads (13%) | catalogued as rs727503491; called by mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 36/980 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- LRFN5 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 68/485 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PSIP1 | c.221G>T p.R74I | Missense Mutation (SNP) | VAF 122/857 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SIRT1 | c.65G>A p.R22K | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2
- TMEM232 | c.817T>C p.S273P | Missense Mutation (SNP) | VAF 152/660 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- LAMC1 | c.2247G>A p.P749= | Silent (SNP) | VAF 88/590 reads (15%) | catalogued as rs763858735, COSV51152856, COSV51161484; called by muse, varscan2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 6/62 reads (10%) | catalogued as rs1262556378; called by muse, mutect2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2
- HNRNPLL | c.-282G>C | 5'UTR (SNP) | VAF 41/286 reads (14%) | called by muse, mutect2, varscan2
- MYF5 | c.*7T>A | 3'UTR (SNP) | VAF 29/396 reads (7%) | called by muse, mutect2
- SSPOP | n.12319C>T | RNA (SNP) | VAF 107/394 reads (27%) | catalogued as rs750922767, COSV65129026; called by muse, mutect2, varscan2
